TCGA case TCGA-DJ-A2Q3 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/acba8d76-999a-4f6d-b3a4-8d7dd0f2bb52

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Papillary carcinoma, columnar cell (the primary disease): ICD-O-3 morphology code: 8344/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.0 years (22,637 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,224 days (3.4 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Lymph nodes positive: 1; Lymph nodes tested: 6; Measurement unit: Centimeters; Tumor depth measurement: 0.6; Tumor length measurement: 0.8; Tumor width measurement: 0.7.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 139 days; Days to treatment end: 139 days; Treatment dose: 99 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 99.3; Prescribed dose units: mCi; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 99 mCi; Pretreatment: rhTSH.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.
2. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 63.0 years (23,022 days); Days to diagnosis: 385 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 404 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Initial disease status: Initial Diagnosis; Treatment dose: 50; Radiosensitizing agent: No.
   Recorded as not given: I-131 Radiation Therapy, for initial diagnosis.

Follow-up (5 entries)
- Days to follow up: 280 days; Disease response: Tumor Free.
- Days to follow up: 356 days; Disease response: Tumor Free.
- Days to follow up: 1,224 days (3.4 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Lymphocytic Thyroiditis / Nodular Hyperplasia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DJ-A2Q3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-DJ-A2Q3-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DJ-A2Q3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DJ-A2Q3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Tall Cell (>= 50% tall cell features); Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Lymphocytic Thyroiditis; History thyroid disease: Nodular Hyperplasia.
- Follow-up form 1: I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 99.3 mCi; I 131 radiation treatment cumulative dose: 99.3 mCi; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: Tumor free.
- Follow-up form 1, New tumor: New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 99.3 mCi; I 131 radiation treatment cumulative dose: 99.3 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Lung; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event diagnosis confirmed by: Pathology; New tumor event histo progression: Yes; New tumor event histo progress type: Poorly differentiated; New tumor event treatment: Surgery; New tumor event treatment: Ebrt; New tumor event treatment: Pharmaceutical therapy; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Imrt; Radiation therapy xrt sensitizers: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,224 days; disease-specific survival: no event (censored), 1,224 days; disease-free interval: no event (censored), 1,224 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 385 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DJ-A2Q3-01A-11D-A18E-01): tumor purity 0.43, ploidy 2, whole-genome doublings 0.
